Somatic mutation profile of tumor specimen TCGA-CV-7435-01A (aliquot TCGA-CV-7435-01A-11D-2129-08) from TCGA case TCGA-CV-7435, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 57.6 years (21,049 days).
Specimen TCGA-CV-7435-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44fef048-9bd6-4924-b0d3-6e67a0975c92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7435-10A (Blood Derived Normal), aliquot TCGA-CV-7435-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f4a82a1-e75f-4ee5-aa4e-e16aef5e95ed

The open-access MAF lists 90 somatic variants for this specimen: 73 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 15, Frame Shift Ins 4, Nonsense Mutation 4, Frame Shift Del 2, Splice Region 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM2A | c.475G>T p.A159S (on ENST00000219054; = p.A80S on NM_001308169.2) | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV54582313; called by muse, mutect2, varscan2
- APC | c.2525A>T p.D842V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.177); catalogued as COSV57325848; called by muse, mutect2, varscan2
- AQP6 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59645840; called by muse, mutect2, varscan2
- ARL13B | c.1169G>A p.R390K (on ENST00000394222 / NM_001174150.2; = p.R283K on NM_144996.4) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.527); catalogued as COSV57396148, COSV57401917; called by muse, mutect2, varscan2
- B4GALT6 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99031011; called by muse, mutect2, varscan2
- BBS10 | c.442T>A p.Y148N | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.173); catalogued as rs1565810142, COSV53878210; called by muse, mutect2, varscan2
- BRINP3 | c.1456A>G p.I486V | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1037373295, COSV66513929; called by muse, mutect2, varscan2
- CDNF | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs558862191, COSV65805602; called by muse, mutect2, varscan2
- CEACAM21 | c.459C>A p.S153R | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99494400; called by muse, mutect2
- CEP350 | c.1510C>G p.L504V | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.109); catalogued as COSV62598882; called by muse, mutect2, varscan2
- CHRNB2 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1469333218, COSV63809354; ClinVar: uncertain significance; called by muse, mutect2
- CIT | c.3268G>T p.E1090* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as COSV55860350; called by muse, mutect2, varscan2
- CNOT1 | c.2298C>A p.F766L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100408830; called by muse, mutect2, varscan2
- CXorf21 | c.475T>A p.S159T | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as COSV66762407; called by muse, mutect2, varscan2
- DCDC1 | c.2170C>T p.H724Y | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV100663024; called by muse, mutect2
- DHRS1 | c.673T>C p.S225P | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV55383417; called by muse, mutect2, varscan2
- DISP3 | c.3862C>T p.H1288Y | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV53820682, COSV53837098; called by muse, mutect2, varscan2
- DNAH3 | c.3883A>T p.T1295S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54504113; called by muse, mutect2, varscan2
- FAM47C | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); catalogued as COSV63723797; called by muse, mutect2, varscan2
- FAM83B | c.821G>A p.R274K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV60919481, COSV60921243; called by muse, mutect2, varscan2
- FUOM | c.410T>A p.L137H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99529383; called by muse, mutect2, varscan2
- GTF3C1 | c.5486G>C p.R1829T | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100649152; called by muse, mutect2, varscan2
- H4C5 | c.185T>G p.F62C | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63486182; called by muse, mutect2, varscan2
- HAL | c.1243A>G p.K415E | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV54116499; called by muse, mutect2, varscan2
- HEPH | c.2840A>G p.D947G (on ENST00000343002; = p.D680G on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as COSV57959137; called by muse, mutect2, varscan2
- HOOK1 | c.1134T>G p.V378= | Splice Region (SNP) | VAF 21/75 reads (28%) | catalogued as COSV64617821; called by muse, mutect2, varscan2
- IAH1 | c.677del p.L226Rfs*8 | Frame Shift Del (DEL) | VAF 32/123 reads (26%) | catalogued as COSV60397564; called by mutect2, pindel, varscan2
- KMT2D | c.1111A>G p.R371G | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV56412071; called by muse, mutect2, varscan2
- LGALS12 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV55369442; called by muse, mutect2, varscan2
- LILRB4 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.112); catalogued as rs529915221, COSV54405073; called by muse, mutect2
- LONRF1 | c.1750C>G p.L584V | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68035960; called by muse, mutect2, varscan2
- LUZP2 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV100419414; called by muse, mutect2
- MAP9 | c.1455G>T p.K485N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100250821, COSV100250836; called by muse, mutect2, varscan2
- MDN1 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV65517355; called by muse, mutect2, varscan2
- MED12L | c.1955A>T p.D652V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV56368856, COSV99853528; called by muse, mutect2, varscan2
- MED13 | c.5830A>T p.M1944L | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as COSV101180902; called by muse, mutect2, varscan2
- MIOS | c.2336G>A p.R779Q | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1260647300, COSV60768296; called by muse, mutect2
- MUC16 | c.13491G>C p.L4497F | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as COSV67445924; called by muse, mutect2, varscan2
- PCDH15 | c.1268C>A p.P423H | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100217882; called by muse, mutect2
- PIP5K1B | c.326T>A p.I109N | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99598415; called by muse, mutect2, varscan2
- PLCL1 | c.3233G>A p.R1078H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.862); catalogued as rs201915547; called by muse, mutect2, varscan2
- PLD1 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV60565431; called by muse, mutect2, varscan2
- PODXL | c.950G>A p.S317N (on ENST00000378555 / NM_001018111.3; = p.S285N on NM_005397.4) | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV59868574; called by muse, mutect2, varscan2
- POMGNT2 | c.236G>C p.C79S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60952678; called by muse, mutect2, varscan2
- PPFIBP1 | c.1492G>T p.G498W (on ENST00000318304 / NM_177444.3; = p.G481W on NM_003622.4) | Missense Mutation (SNP) | VAF 13/303 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV57287766; called by muse, mutect2
- PPP2R2B | c.196G>A p.E66K (on ENST00000394409; = p.E132K on NM_181674.2) | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV60753865; called by muse, mutect2, varscan2
- PURG | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as COSV53296205; called by muse, mutect2, varscan2
- RNF135 | c.1165T>C p.F389L | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60434544; called by muse, mutect2, varscan2
- ROCK1 | c.3686A>G p.H1229R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV67694537; called by muse, mutect2, varscan2
- S1PR4 | c.1064T>A p.L355Q | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.575); catalogued as COSV99858995; called by muse, mutect2, varscan2
- SEMA3C | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759005489, COSV54841535; called by muse, mutect2
- SENP1 | c.862A>G p.T288A | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1457145914, COSV99136848; called by muse, mutect2, varscan2
- SLC26A11 | c.1579A>G p.T527A | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV63278902; called by muse, mutect2, varscan2
- SLC29A2 | c.755G>A p.S252N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as rs758105483, COSV60802831; called by muse, mutect2, varscan2
- SLC9C2 | c.2690G>C p.G897A | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV62943879; called by muse, mutect2, varscan2
- SRRM2 | c.1902G>T p.R634S | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs768055388, COSV100070492, COSV57067710; called by muse, mutect2, varscan2
- SYNE2 | c.6729C>G p.N2243K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59940132, COSV59947099; called by muse, mutect2, varscan2
- SYT16 | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV70855067; called by muse, mutect2, varscan2
- TET1 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV65382154; called by muse, mutect2, varscan2
- TEX44 | c.624A>C p.E208D | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV100009646; called by muse, mutect2
- TRMO | c.638A>G p.H213R | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV64291340; called by muse, mutect2, varscan2
- VWA7 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.344); catalogued as COSV100791791; called by muse, mutect2, varscan2
- WWC1 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV54646066; called by muse, mutect2, varscan2
- XPR1 | c.1075C>T p.L359F | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV62554601; called by muse, mutect2, varscan2
- ZNF433 | c.1023A>C p.K341N | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as COSV100794968; called by muse, mutect2
- ZNF630 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV52094995; called by muse, mutect2, varscan2
- ZNF99 | c.2125G>C p.E709Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV68054805; called by muse, mutect2, varscan2
- CD207 | c.612dup p.N205Efs*14 | Frame Shift Ins (INS) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
- FAT1 | c.1129dup p.S377Kfs*2 | Frame Shift Ins (INS) | VAF 29/86 reads (34%) | called by mutect2, pindel, varscan2
- GTF3C6 | c.590dup p.P198Tfs*3 | Frame Shift Ins (INS) | VAF 28/109 reads (26%) | called by mutect2, pindel, varscan2
- PIGK | c.471del p.L158* | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- USP21 | c.984dup p.A329Cfs*20 | Frame Shift Ins (INS) | VAF 35/127 reads (28%) | called by mutect2, pindel, varscan2
- AGTPBP1 | c.252T>A p.L84= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV61268719; called by muse, mutect2
- AVPI1 | c.312G>A p.L104= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV65697294; called by muse, mutect2, varscan2
- DISP3 | c.3861G>T p.R1287= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV53820655; called by muse, mutect2, varscan2
- DNAH2 | c.12519G>C p.G4173= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV66716524; called by muse, mutect2, varscan2
- EIF3H | c.450C>T p.L150= | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as rs1210190761, COSV99411677; called by muse, mutect2, varscan2
- EPHA10 | c.456C>T p.I152= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs774735737, COSV60405081; called by muse, mutect2, varscan2
- FANCB | c.348T>C p.N116= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV60758866; called by muse, mutect2, varscan2
- FZD7 | c.367C>T p.L123= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as rs781228423, COSV99637003; called by muse, mutect2, varscan2
- HSPA2 | c.786C>A p.A262= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV99904793; called by muse, mutect2, varscan2
- LRRC15 | c.471C>T p.H157= | Silent (SNP) | VAF 33/294 reads (11%) | catalogued as rs143343570; called by muse, mutect2, varscan2
- MROH2B | c.324C>T p.F108= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs371986783; called by muse, mutect2, varscan2
- ODF2 | c.51G>A p.K17= (on ENST00000434106 / NM_153433.2; = p.K61= on NM_153432.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV63545779; called by muse, mutect2, varscan2
- RAD50 | c.250C>T p.L84= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV54748671, COSV99528786; called by muse, mutect2, varscan2
- UROC1 | c.795C>T p.C265= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV52030102; called by muse, mutect2, varscan2
- ZNF365 | c.786G>A p.E262= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV101237936; called by muse, mutect2, varscan2
- C10orf90 | c.1243+1128T>C | Intron (SNP) | VAF 31/137 reads (23%) | catalogued as COSV99503466; called by muse, mutect2, varscan2
- WASF4P | n.272T>A | RNA (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
